Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RO, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RO-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:**PART 1: ESOPHAGUS, ESOPHAGECTOMY -**

- A. ADENOCARCINOMA, MODERATELY DIFFERENTIATED, 5CM, INVASIVE INTO THE SUBMUCOSA (pT1b).
- B. NEGATIVE FOR ANGIOLYMPHATIC AND PERINEURAL INVASION.
- C. SURGICAL RESECTION MARGINS (PROXIMAL ESOPHAGUS, DISTAL STOMACH AND ADVENTITIAL MARGIN) ARE NEGATIVE FOR NEOPLASTIC INVOLVEMENT.
- D. THE TUMOR COMES WITHIN 0.2CM OF THE RADIAL/ADVENTITIAL SURGICAL RESECTION MARGIN.
- E. 1.6CM DISTALLY FROM THE MAIN TUMOR IS A 0.9CM FOCUS OF HIGH GRADE DYSPLASIA.
- F. BACKGROUND GASTROESOPHAGEAL MUCOSA WITH BARRETT'S MUCOSA.
- G. THERE IS NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES (0/9).
- H. AJCC STAGING: pT1b N0.

PART 2: LYMPH NODE, SUBCARINAL NEAR LEFT MAIN BRONCHUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 3: LYMPH NODE, SUBCARINAL NEAR RIGHT MAIN BRONCHUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 4: LYMPH NODE, SUBCARINAL NEAR PERICARDIUM, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 5: LYMPH NODE, SUBCARINAL NEAR THORACIC DUCT, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 6: LYMPH NODE, PARAESOPHAGEAL NEAR LEFT VEIN, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 7: LYMPH NODE, PARAESOPHAGEAL NEAR RIGHT CRUS, EXCISION -
A. FIBROADIPOSE TISSUE, NO LYMPH NODES IDENTIFIED.
B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 8: LYMPH NODE, NEAR VAGUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 9: LYMPH NODE, SUBCARINAL NEAR ATRIUM, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 10: LYMPH NODE, LESSER CURVE, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 11: LYMPH NODE, NEAR LEFT GASTRIC ARTERY, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 12: LYMPH NODE, GASTRIC FAT, EXCISION -
A. SKELETAL MUSCLE AND FIBROADIPOSE TISSUE, NO LYMPH NODE IDENTIFIED.
B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 13: LYMPH NODE, NEAR AZYGOUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 14: LYMPH NODE, FAT PAD, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 15: LYMPH NODE, PERIESOPHAGEAL AND FAT PAD NEAR DIAPHRAGM, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2).

PART 16: ANASTOMOTIC RINGS, EXCISION -
A. RING OF STOMACH WITH OXYNTIC MUCOSA.
B. RING OF ESOPHAGUS WITH SKELETAL MUSCLE.
C. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 17: FINAL GASTRIC MARGIN, EXCISION -
A. STOMACH WITH OXYNTIC MUCOSA.
B. THERE IS NO EVIDENCE OF MALIGNANCY.

ICD-O-3

Adenocarcinoma NOS
8/40/13Gastroesophageal junction
C16.0

7/12/13

**COMMENT:**

Part one. Esophagus, esophagectomy:

The 5.0cm adenocarcinoma present at the gastroesophageal junction is similar to previous biopsy [REDACTED] by report as slides are not available for review. The tumor comes to within 2mm of the adventitial surgical resection margin. There is a separate 0.9cm lesion with high grade dysplasia located 1.6 cm distally to the main 5cm adenocarcinoma. No angiolymphatic invasion is seen using double immunohistochemical stain D240/AE1/3.

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS**

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Esophagogastric junction (EGJ) region (tumor involves EGJ and epicenter within 5cm of EGJ)
TUMOR SIZE: Greatest dimension: 5 cm
Additional dimensions: 2.3 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G2

PATHOLOGIC STAGING (pTNM)

pT1b
pN0
Number of lymph nodes examined: 22
Number of lymph nodes involved: 0
pM Not applicable
No prior treatment

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Proximal margin uninvolved by dysplasia
Proximal margin uninvolved by intestinal metaplasia
Distal margin uninvolved by invasive carcinoma
Distal margin uninvolved by dysplasia
Distal margin uninvolved by intestinal metaplasia
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 4 mm
Specify margin: adventitial margin

ANGIOLYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)
High grade dysplasia

HIP-VA Discrepancy		

Source: NCI Genomic Data Commons file f39a78c8-a149-47f6-8916-c55f0d91b97c (TCGA-IN-A6RO.C0E5F045-3F12-45CF-A6A4-034D99F2A719.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).